Somatic mutation profile of tumor specimen PCProject_0149_T1_WES (aliquot PCProject_0149_T1_WES_1) from CMI case PCProject_0149, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.4 years (23,511 days).
Specimen PCProject_0149_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06a2504a-4522-41f8-b136-2cc686cc87c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0149_SALIVA (Saliva), aliquot PCProject_0149_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c4754d1-0b12-4728-9636-68261be7c967

The open-access MAF lists 44 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Frame Shift Del 4, Intron 3, Nonsense Mutation 2, Splice Region 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSI | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775494433; called by muse, mutect2, varscan2
- DNHD1 | c.13219C>T p.R4407* | Nonsense Mutation (SNP) | VAF 17/179 reads (9%) | catalogued as rs1030679647, COSV54441033; called by muse, mutect2
- HS3ST3A1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773253555; called by muse, mutect2, varscan2
- KCNQ2 | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs796052638; called by muse, mutect2, varscan2
- KIAA1549L | c.2437G>A p.G813S (on ENST00000321505; = p.G1110S on NM_012194.3) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); catalogued as COSV99682882; called by muse, mutect2
- KPRP | c.1535A>T p.D512V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100908690; called by muse, mutect2, varscan2
- MYO16 | c.4748C>T p.P1583L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1380947259; called by muse, mutect2
- OSBPL7 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as rs748703801; called by muse, mutect2, varscan2
- QSER1 | c.2926C>T p.P976S (on ENST00000399302; = p.P1105S on NM_001076786.3) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1008435544; called by muse, mutect2, varscan2
- SEMA3E | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs780025635, COSV57096393; called by muse, mutect2
- SEMA5B | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1286796333; called by muse, mutect2, varscan2
- TAOK1 | c.557C>G p.P186R | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55590641; called by muse, varscan2
- WDR11 | c.1439del p.N480Tfs*32 | Frame Shift Del (DEL) | VAF 15/135 reads (11%) | catalogued as rs747938475; called by mutect2, pindel, varscan2
- ASXL2 | c.1943G>T p.S648I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BRCA2 | c.5660_5663del p.T1887Kfs*21 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- C1orf87 | c.79T>A p.F27I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CPSF6 | c.1073A>T p.N358I | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- EOMES | c.778G>T p.V260F | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- ERCC6 | c.2411A>C p.K804T | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- FSD1L | c.354A>C p.Q118H (on ENST00000481272 / NM_001145313.3; = p.Q86H on NM_031919.5) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.428); called by muse, mutect2
- LAMA5 | c.1629T>A p.C543* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- MUC16 | c.39356A>T p.D13119V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2
- MUC16 | c.10744A>T p.T3582S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- RBBP8NL | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by mutect2, varscan2
- RBM15 | c.1759G>T p.V587L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- RPN2 | c.1005T>G p.N335K | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2
- SLC1A2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SLC2A12 | c.1561_1562del p.V521Nfs*2 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.1785T>A p.A595= | Splice Region (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- TPD52 | c.26del p.Y9Lfs*14 | Frame Shift Del (DEL) | VAF 16/122 reads (13%) | called by mutect2, pindel, varscan2
- TYW1B | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- YJEFN3 | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZP2 | c.247C>T p.L83F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARAP1 | c.3384G>A p.V1128= (on ENST00000393609 / NM_001040118.2; = p.V883= on NM_015242.4) | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs574284921; called by muse, mutect2, varscan2
- CDC45 | c.1446G>A p.K482= | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, varscan2
- DAO | c.987C>G p.L329= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs1329285393; called by muse, mutect2, varscan2
- FCGBP | c.5784C>T p.A1928= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs1292505819; called by muse, mutect2, varscan2
- IFITM1 | c.102C>T p.P34= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs752987131, COSV60249122; called by muse, mutect2, varscan2
- PHLDA1 | c.273C>A p.L91= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- SLC9C1 | c.201C>T p.Y67= | Silent (SNP) | VAF 10/125 reads (8%) | catalogued as rs202221594, COSV59889256; called by muse, mutect2
- DPF3 | c.871+2953G>A | Intron (SNP) | VAF 34/202 reads (17%) | catalogued as rs538363982, COSV63499045; called by muse, mutect2, varscan2
- DPY19L4 | c.611+4683A>T | Intron (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- HNRNPU | c.-2C>A | 5'UTR (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- KYNU | c.582+45T>G | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, varscan2
